Somatic mutation profile of tumor specimen TCGA-A5-A1OJ-01A (aliquot TCGA-A5-A1OJ-01A-11D-A14G-09) from TCGA case TCGA-A5-A1OJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 31.9 years (11,635 days).
Specimen TCGA-A5-A1OJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddf61086-218b-4b01-935e-52f1d76e18ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A1OJ-10A (Blood Derived Normal), aliquot TCGA-A5-A1OJ-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/564d1025-1338-491b-bafd-32a20993d826

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 48/83 reads (58%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as rs148791847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAA1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs749249005, COSV100086450; called by muse, mutect2, varscan2
- ACTR8 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.124); catalogued as COSV51635237; called by muse, mutect2
- ADD2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782075109, COSV52455933; called by muse, mutect2, varscan2
- AFF1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57119370; called by muse, mutect2, varscan2
- AKAP4 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs782110275, COSV100654363; called by muse, mutect2, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2
- ASAP1 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs746266855, COSV63045192; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CNTNAP5 | c.3076T>C p.S1026P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.971); catalogued as COSV101444206; called by muse, mutect2
- CRYBB2 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101236775; called by muse, mutect2, varscan2
- CXorf38 | c.268C>A p.H90N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100010525; called by muse, mutect2, varscan2
- CYSLTR1 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100964755; called by muse, mutect2, varscan2
- DYM | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53993514; called by muse, mutect2, varscan2
- ECPAS | c.3511C>T p.R1171* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs1303956469, COSV99399284; called by muse, mutect2, varscan2
- FGFR1 | c.848C>T p.P283L (on ENST00000447712 / NM_023110.3; = p.P281L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); catalogued as rs1554562012, CM070120, COSV58342829; called by muse, mutect2, varscan2
- FRMPD2 | c.2882G>T p.G961V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220966193, COSV100564181; called by muse, mutect2, varscan2
- ITGB1 | c.2091C>G p.D697E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV56488058; called by muse, mutect2, varscan2
- JAG1 | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54753471; called by muse, mutect2, varscan2
- KCNQ3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101196430; called by muse, mutect2
- KRTAP17-1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | PolyPhen benign (0.347); catalogued as rs76002044, COSV61972111, COSV61972387; called by muse, mutect2, varscan2
- MAJIN | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs376771758; called by muse, mutect2, varscan2
- MYO18B | c.6637G>A p.V2213I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs560154518, COSV59137511; called by muse, varscan2
- MYO9B | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427787160, COSV101261935; called by muse, mutect2, varscan2
- NFXL1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs775957092, COSV67430964, COSV67432041; called by muse, mutect2, varscan2
- OR7G3 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100555754; called by muse, mutect2, varscan2
- PALLD | c.3017G>A p.R1006Q (on ENST00000505667 / NM_001166108.2; = p.R989Q on NM_016081.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs777057820, COSV54977792; called by muse, mutect2, varscan2
- POU3F1 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100884724; called by muse, varscan2
- SFMBT2 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100739637; called by muse, mutect2
- SOX17 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99810843; called by muse, mutect2, varscan2
- SPRYD3 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100036649; called by muse, mutect2
- TAF1 | c.3052C>A p.R1018S (on ENST00000373790 / NM_138923.4; = p.R1039S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52115681; called by muse, mutect2, varscan2
- TENM1 | c.4892T>C p.M1631T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV100950929; called by muse, mutect2, varscan2
- TNS4 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368737342; called by mutect2, varscan2
- TYR | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs753049427, CD085008, COSV54480825; called by muse, mutect2
- BNC1 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- FBXO30 | c.976_980dup p.S328Nfs*15 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1D-43 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CASR | c.276G>A p.T92= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs201013419, COSV99949475, COSV99949478; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP5 | c.3078C>T p.S1026= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1442949367, COSV70473271; called by muse, mutect2
- DNAI2 | c.1194G>A p.S398= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs556547267, COSV100210064; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GCNA | c.705C>T p.P235= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs138010303, COSV101032699; called by muse, mutect2, varscan2
- KLF5 | c.906G>T p.P302= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100890560; called by muse, mutect2, varscan2
- NINL | c.57C>T p.C19= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs753697173, COSV53998606; called by muse, mutect2, varscan2
- OR2M7 | c.633T>C p.V211= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as COSV100522686; called by muse, mutect2, varscan2
- PCDHGA8 | c.1953G>A p.Q651= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV99546718; called by muse, mutect2, varscan2
- PID1 | c.510C>T p.T170= (on ENST00000354069 / NM_001330156.1; = p.T168= on NM_017933.5) | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs139231184; called by muse, mutect2, varscan2
- SELENOI | c.147G>A p.A49= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs372437710, COSV99564304; called by muse, mutect2
- SLC47A1 | c.399C>T p.L133= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV99565647; called by muse, mutect2, varscan2
- TNXB | c.6288C>T p.H2096= (on ENST00000647633; = p.H1849= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs761764903, COSV100926623; called by muse, mutect2, varscan2
- ZNF76 | c.990G>A p.S330= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs761565684, COSV57591839; called by muse, mutect2, varscan2
- IL9R | c.29-1416C>T | Intron (SNP) | VAF 40/174 reads (23%) | catalogued as rs750868989, COSV99730203; called by muse, mutect2, varscan2
